Gene-level copy-number profile of tumor specimen TCGA-AR-A1AV-01A from TCGA case TCGA-AR-A1AV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.1 years (24,875 days).
Specimen TCGA-AR-A1AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.135f0af7-da27-4a64-b7a5-16c0eaa1df7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7432b368-411a-4e7a-a764-3a4a0b641821

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,158; copy number 3: 28,000; copy number 4: 19,453; copy number 5: 2,687; copy number 6: 2,632; copy number 7: 2,046; copy number 8: 769; copy number 10: 33; copy number 13: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AV-01A-21D-A12N-01): tumor purity 0.65, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,890 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–8 (broad region; genes not listed).
- chr11:59,491,652–60,160,822, 33 genes, copy number 10: OR4D8P, OR4D11, OR4D9, OR4D7P, AP003778.1, LINC02739, AP000442.1, OSBP, MIR3162, PATL1, AP000640.2, RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705.
- chr11:60,515,392–61,892,051, 63 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:66,975,277–71,252,577, 145 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr11:74,696,429–75,768,647, 44 genes, copy number 7: CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1.
- chr11:75,775,904–75,776,929, 1 gene, copy number 7: AP001922.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
